Somatic mutation profile of tumor specimen TCGA-FJ-A3Z7-01A (aliquot TCGA-FJ-A3Z7-01A-12D-A23M-08) from TCGA case TCGA-FJ-A3Z7, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Bladder, NOS; AJCC pathologic stage: Stage IV; Tumor grade: High Grade; Age at diagnosis: 76.8 years (28,052 days).
Specimen TCGA-FJ-A3Z7-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 24692a1a-fda9-4f4f-a8d5-957b3513a91a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-FJ-A3Z7-10A (Blood Derived Normal), aliquot TCGA-FJ-A3Z7-10A-01D-A23K-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5842a3d0-762f-4194-af3e-94b285344835

The open-access MAF lists 357 somatic variants for this specimen: 271 protein-altering or splice-affecting, 77 silent, 9 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 236, Silent 77, Nonsense Mutation 23, Splice Site 5, Intron 4, RNA 3, Frame Shift Del 2, Nonstop Mutation 2, Splice Region 2, 5'UTR 1, Frame Shift Ins 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AAMP | c.1183G>C p.D395H | Missense Mutation (SNP) | VAF 34/201 reads (17%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.477); catalogued as COSV50307893; called by muse, mutect2, varscan2
- ABCA13 | c.534C>G p.I178M | Missense Mutation (SNP) | VAF 35/193 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.824); catalogued as COSV70031699; called by muse, mutect2, varscan2
- ABCB4 | c.1345G>A p.D449N | Missense Mutation (SNP) | VAF 91/376 reads (24%) | SIFT tolerated (0.44); PolyPhen benign (0.062); catalogued as COSV55936434; called by muse, mutect2, varscan2
- ABCC8 | c.1591A>T p.T531S | Missense Mutation (SNP) | VAF 13/80 reads (16%) | SIFT tolerated (0.4); PolyPhen benign (0.038); catalogued as COSV56851841; called by muse, mutect2, varscan2
- AC068580.4 | c.149G>A p.G50D | Missense Mutation (SNP) | VAF 16/64 reads (25%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.276); catalogued as COSV52588551; called by muse, mutect2, varscan2
- ACVR1C | c.1222G>C p.G408R | Missense Mutation (SNP) | VAF 38/240 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.348); catalogued as COSV54646850; called by muse, mutect2, varscan2
- ADH6 | c.605G>C p.G202A | Missense Mutation (SNP) | VAF 61/353 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.739); catalogued as COSV52956526; called by muse, mutect2, varscan2
- ADORA1 | c.913G>A p.D305N | Missense Mutation (SNP) | VAF 17/58 reads (29%) | SIFT tolerated (0.51); PolyPhen benign (0.028); catalogued as COSV55142786; called by muse, mutect2, varscan2
- AKR1E2 | c.921-1G>A p.X307_splice | Splice Site (SNP) | VAF 15/128 reads (12%) | catalogued as COSV53630711; called by muse, mutect2, varscan2
- AMER1 | c.877G>A p.V293I | Missense Mutation (SNP) | VAF 48/162 reads (30%) | SIFT tolerated (0.47); PolyPhen benign (0.007); catalogued as COSV57661955; called by muse, mutect2, varscan2
- AMER1 | c.592G>C p.E198Q | Missense Mutation (SNP) | VAF 17/53 reads (32%) | SIFT tolerated (0.06); PolyPhen benign (0.343); catalogued as COSV57660170, COSV57664825; called by muse, mutect2, varscan2
- AMER2 | c.1288G>C p.E430Q | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT tolerated (0.37); PolyPhen benign (0.015); catalogued as COSV63438113; called by muse, mutect2, varscan2
- ANKFN1 | c.697G>C p.E233Q | Missense Mutation (SNP) | VAF 32/171 reads (19%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as COSV59446483, COSV59449614; called by muse, mutect2, varscan2
- ARHGAP20 | c.59C>G p.S20C | Missense Mutation (SNP) | VAF 7/15 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV52812974, COSV99505414; called by muse, mutect2, varscan2
- ARHGEF9 | c.952G>C p.E318Q | Missense Mutation (SNP) | VAF 17/52 reads (33%) | SIFT tolerated (0.14); PolyPhen benign (0.062); catalogued as COSV53639357; called by muse, mutect2, varscan2
- ARMC8 | c.1134+1G>A p.X378_splice (on ENST00000469044 / NM_001363941.2; = p.V365M on NM_014154.4 and 1 other RefSeq transcript) | Splice Site (SNP) | VAF 26/104 reads (25%) | catalogued as COSV61768727; called by muse, mutect2, varscan2
- AUTS2 | c.2185C>G p.P729A | Missense Mutation (SNP) | VAF 17/85 reads (20%) | SIFT tolerated (0.47); PolyPhen benign (0.227); catalogued as COSV61408431; called by muse, mutect2, varscan2
- AVPR2 | c.791C>T p.A264V | Missense Mutation (SNP) | VAF 20/40 reads (50%) | SIFT tolerated (0.09); PolyPhen benign (0.395); catalogued as COSV61686369; called by muse, mutect2, varscan2
- BAP1 | c.1891G>C p.E631Q | Missense Mutation (SNP) | VAF 19/111 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.205); catalogued as COSV56235325, COSV56238458; called by muse, mutect2, varscan2
- BBS9 | c.2269C>G p.L757V (on ENST00000242067 / NM_001348036.1; = p.L717V on NM_014451.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 17/161 reads (11%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.74); catalogued as COSV54167564, COSV54171808; called by muse, mutect2, varscan2
- BCAR3 | c.2358G>C p.L786F | Missense Mutation (SNP) | VAF 80/159 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV53075959; called by muse, mutect2, varscan2
- BEST2 | c.90A>T p.K30N | Missense Mutation (SNP) | VAF 19/52 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV50366731; called by muse, mutect2, varscan2
- BPIFB3 | c.976G>A p.E326K | Missense Mutation (SNP) | VAF 31/132 reads (23%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.516); catalogued as COSV64957462; called by muse, mutect2, varscan2
- BPTF | c.4558G>C p.E1520Q | Missense Mutation (SNP) | VAF 23/96 reads (24%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.273); catalogued as COSV58838823; called by muse, mutect2, varscan2
- BRAT1 | c.623C>T p.S208F | Missense Mutation (SNP) | VAF 48/214 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.65); catalogued as COSV61395765; called by muse, mutect2, varscan2
- BRDT | c.532C>A p.P178T | Missense Mutation (SNP) | VAF 13/100 reads (13%) | SIFT tolerated (0.19); PolyPhen benign (0.115); catalogued as COSV100746040, COSV62865393; called by muse, mutect2, varscan2
- C19orf57 | c.939G>C p.Q313H | Missense Mutation (SNP) | VAF 16/37 reads (43%) | SIFT tolerated (0.18); PolyPhen benign (0.069); catalogued as COSV60968638; called by muse, mutect2, varscan2
- CCDC173 | c.1624C>T p.Q542* | Nonsense Mutation (SNP) | VAF 19/78 reads (24%) | catalogued as COSV53644584, COSV53644665; called by muse, mutect2, varscan2
- CDH2 | c.214G>C p.E72Q | Missense Mutation (SNP) | VAF 30/105 reads (29%) | SIFT tolerated (0.33); PolyPhen benign (0.048); catalogued as COSV52282955; called by muse, mutect2, varscan2
- CDK16 | c.257C>T p.S86L | Missense Mutation (SNP) | VAF 15/40 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.027); catalogued as COSV52092417; called by muse, mutect2, varscan2
- CEBPZ | c.1876C>T p.H626Y | Missense Mutation (SNP) | VAF 57/126 reads (45%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.544); catalogued as COSV52206752; called by muse, mutect2, varscan2
- CENPK | c.679C>T p.P227S | Missense Mutation (SNP) | VAF 14/73 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV54468478; called by muse, mutect2, varscan2
- CFAP43 | c.2142-1G>A p.X714_splice | Splice Site (SNP) | VAF 11/48 reads (23%) | catalogued as COSV53378563; called by muse, mutect2, varscan2
- CHEK2 | c.1258G>A p.E420K (on ENST00000382580 / NM_001005735.2; = p.E377K on NM_007194.4) | Missense Mutation (SNP) | VAF 24/106 reads (23%) | SIFT tolerated (0.13); PolyPhen benign (0.16); catalogued as COSV60421436; called by muse, mutect2, varscan2
- CHEK2 | c.1196C>A p.S399* (on ENST00000382580 / NM_001005735.2; = p.S356* on NM_007194.4) | Nonsense Mutation (SNP) | VAF 14/58 reads (24%) | catalogued as CM1511946, COSV60423853; called by muse, varscan2
- CHEK2 | c.1144C>T p.H382Y (on ENST00000382580 / NM_001005735.2; = p.H339Y on NM_007194.4) | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs371207635; ClinVar: uncertain significance; called by muse, varscan2
- CLN3 | c.1063C>G p.L355V (on ENST00000360019 / NM_001286104.2; = p.L379V on NM_000086.2) | Missense Mutation (SNP) | VAF 20/101 reads (20%) | SIFT tolerated (0.08); PolyPhen benign (0.04); catalogued as COSV61106138; called by muse, mutect2, varscan2
- CLVS1 | c.959C>T p.S320L | Missense Mutation (SNP) | VAF 16/49 reads (33%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.977); catalogued as rs757573507, COSV57976655; called by muse, mutect2, varscan2
- CNGB1 | c.106G>C p.E36Q | Missense Mutation (SNP) | VAF 15/69 reads (22%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.585); catalogued as COSV51901896, COSV51907094; called by muse, mutect2, varscan2
- CSF1 | c.126G>A p.M42I | Missense Mutation (SNP) | VAF 13/73 reads (18%) | SIFT tolerated (0.65); PolyPhen benign (0.012); catalogued as COSV60033638; called by muse, mutect2, varscan2
- CSMD3 | c.7992G>T p.L2664F (on ENST00000297405 / NM_001363185.1; = p.L2560F on NM_052900.3) | Missense Mutation (SNP) | VAF 36/148 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52205114; called by muse, mutect2, varscan2
- DCLK1 | c.869C>T p.S290L | Missense Mutation (SNP) | VAF 81/196 reads (41%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as COSV55191165; called by muse, mutect2, varscan2
- DCTN4 | c.985C>G p.L329V | Missense Mutation (SNP) | VAF 28/49 reads (57%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.992); catalogued as COSV69781725; called by muse, mutect2
- DDX39B | c.693G>C p.L231F | Missense Mutation (SNP) | VAF 27/149 reads (18%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.898); catalogued as COSV63331502; called by muse, mutect2, varscan2
- DENND4B | c.2903G>A p.R968Q | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as rs748707602, COSV63408603; called by muse, mutect2, varscan2
- DENND4B | c.2143G>C p.E715Q | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.831); catalogued as rs761924019, COSV63409809; called by muse, mutect2, varscan2
- DENND4B | c.2027G>A p.G676E | Missense Mutation (SNP) | VAF 29/217 reads (13%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.452); catalogued as COSV63409814; called by muse, mutect2, varscan2
- DHPS | c.147C>A p.F49L | Missense Mutation (SNP) | VAF 15/64 reads (23%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as COSV52951591, COSV52951708, COSV52952106; called by muse, mutect2, varscan2
- DHX30 | c.1137G>C p.Q379H (on ENST00000445061 / NM_138615.3; = p.Q340H on NM_014966.3) | Missense Mutation (SNP) | VAF 67/194 reads (35%) | SIFT tolerated (0.28); PolyPhen benign (0.001); catalogued as COSV53138511; called by muse, varscan2
- DHX40 | c.2237G>C p.R746T | Missense Mutation (SNP) | VAF 20/102 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.15); catalogued as COSV52068163; called by muse, mutect2, varscan2
- DNAH5 | c.2965C>T p.H989Y | Missense Mutation (SNP) | VAF 32/174 reads (18%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as COSV54231337; called by muse, mutect2, varscan2
- DNHD1 | c.11824C>G p.L3942V | Missense Mutation (SNP) | VAF 18/69 reads (26%) | SIFT tolerated (0.07); PolyPhen benign (0.021); catalogued as COSV54437439; called by muse, mutect2, varscan2
- DTNBP1 | c.46T>A p.F16I | Missense Mutation (SNP) | VAF 27/234 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as rs1296948691, COSV59040891; called by muse, mutect2, varscan2
- EDRF1 | c.650G>T p.G217V | Missense Mutation (SNP) | VAF 13/55 reads (24%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.885); catalogued as COSV61764357; called by muse, mutect2, varscan2
- EEFSEC | c.574G>A p.E192K | Missense Mutation (SNP) | VAF 25/206 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.047); catalogued as COSV54626924; called by muse, mutect2, varscan2
- EIF1 | c.250C>T p.Q84* | Nonsense Mutation (SNP) | VAF 18/141 reads (13%) | catalogued as COSV100179557, COSV60422872; called by muse, mutect2, varscan2
- ENOX1 | c.1336G>A p.E446K | Missense Mutation (SNP) | VAF 14/193 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV54902571; called by muse, mutect2
- EPB41L5 | c.421C>G p.L141V | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55353266; called by muse, mutect2, varscan2
- EPHA6 | c.1043G>A p.G348E | Missense Mutation (SNP) | VAF 81/154 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67576033; called by muse, mutect2, varscan2
- EPHX3 | c.880G>C p.E294Q | Missense Mutation (SNP) | VAF 7/48 reads (15%) | SIFT tolerated (0.31); PolyPhen benign (0.026); catalogued as COSV55655801; called by muse, mutect2, varscan2
- ERBIN | c.2531C>T p.S844F | Missense Mutation (SNP) | VAF 15/53 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.049); catalogued as rs776808091, COSV52318186; called by muse, mutect2, varscan2
- FAM171A1 | c.214G>A p.G72S | Missense Mutation (SNP) | VAF 29/50 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65316829; called by muse, mutect2, varscan2
- FAM47B | c.739C>G p.L247V | Missense Mutation (SNP) | VAF 28/97 reads (29%) | SIFT tolerated (0.11); PolyPhen benign (0.071); catalogued as COSV61454477, COSV61455676; called by muse, mutect2, varscan2
- FANCA | c.3665C>T p.P1222L | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.485); catalogued as rs374537936, COSV99235286; called by muse, varscan2
- FLT1 | c.3803C>T p.S1268L | Missense Mutation (SNP) | VAF 23/72 reads (32%) | SIFT tolerated (0.12); PolyPhen benign (0.028); catalogued as rs368266056, COSV56724189; called by muse, mutect2, varscan2
- GAL3ST1 | c.958G>C p.E320Q | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.981); catalogued as COSV58892846; called by muse, mutect2, varscan2
- GET3 | c.433G>T p.A145S | Missense Mutation (SNP) | VAF 20/80 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.568); catalogued as COSV62002491; called by muse, mutect2, varscan2
- GPATCH8 | c.3511G>A p.E1171K | Missense Mutation (SNP) | VAF 40/250 reads (16%) | SIFT tolerated (0.44); PolyPhen benign (0.024); catalogued as COSV59195402; called by muse, mutect2, varscan2
- GPD1L | c.556C>G p.P186A | Missense Mutation (SNP) | VAF 112/457 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as COSV56990432; called by muse, mutect2, varscan2
- GRIN2A | c.4126C>T p.R1376C | Missense Mutation (SNP) | VAF 14/98 reads (14%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.761); catalogued as rs1426934537, COSV58023359, COSV58024387; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GSK3B | c.1194A>T p.S398= (on ENST00000264235 / NM_001146156.2; = p.S411= on NM_002093.4) | Splice Region (SNP) | VAF 32/102 reads (31%) | catalogued as COSV51777011; called by muse, mutect2, varscan2
- GTF2IRD1 | c.823C>G p.P275A | Missense Mutation (SNP) | VAF 13/70 reads (19%) | SIFT tolerated (0.08); PolyPhen benign (0.018); catalogued as rs1554345441, COSV56084708, COSV56087460; called by muse, mutect2, varscan2
- H1-10 | c.111G>C p.K37N | Missense Mutation (SNP) | VAF 3/12 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.218); catalogued as rs771940616; called by muse, mutect2
- H1-3 | c.243C>G p.I81M | Missense Mutation (SNP) | VAF 67/215 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs778271229, COSV55096687; called by muse, mutect2, varscan2
- H3C6 | c.292G>A p.E98K | Missense Mutation (SNP) | VAF 76/171 reads (44%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.904); catalogued as COSV64519644, COSV64519726; called by muse, mutect2, varscan2
- HADHA | c.796G>C p.E266Q | Missense Mutation (SNP) | VAF 79/238 reads (33%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV66107655; called by muse, mutect2, varscan2
- HEATR4 | c.2283G>C p.K761N | Missense Mutation (SNP) | VAF 46/87 reads (53%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as COSV58573517; called by muse, mutect2, varscan2
- HHIPL2 | c.1940C>T p.S647F | Missense Mutation (SNP) | VAF 24/190 reads (13%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as rs772713730, COSV58565674; called by muse, mutect2, varscan2
- HMGCLL1 | c.382C>A p.P128T | Missense Mutation (SNP) | VAF 32/165 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV51446026, COSV51452277; called by muse, mutect2, varscan2
- HNRNPUL1 | c.157G>C p.E53Q | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as COSV54563306; called by muse, mutect2, varscan2
- HSPG2 | c.4465G>C p.D1489H | Missense Mutation (SNP) | VAF 5/9 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV65972621; called by muse, mutect2, varscan2
- IBSP | c.707A>C p.E236A | Missense Mutation (SNP) | VAF 11/53 reads (21%) | SIFT tolerated (0.05); PolyPhen benign (0.007); catalogued as COSV56896062; called by muse, mutect2, varscan2
- IKBIP | c.244G>C p.E82Q | Missense Mutation (SNP) | VAF 9/65 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.44); catalogued as COSV54489910; called by muse, mutect2, varscan2
- IL12RB1 | c.1613G>C p.S538T | Missense Mutation (SNP) | VAF 4/35 reads (11%) | SIFT tolerated (0.12); PolyPhen benign (0.03); catalogued as COSV74045551; called by muse, mutect2
- IL7R | c.285G>C p.E95D | Missense Mutation (SNP) | VAF 27/258 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.014); catalogued as COSV57406067, COSV57409307; called by muse, mutect2, varscan2
- INTS3 | c.2732C>G p.S911C | Missense Mutation (SNP) | VAF 14/128 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV55164067; called by muse, mutect2, varscan2
- IQCA1 | c.472A>G p.S158G | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as rs1382818376, COSV54504055; called by muse, mutect2, varscan2
- IQGAP3 | c.1678C>T p.P560S | Missense Mutation (SNP) | VAF 27/81 reads (33%) | SIFT tolerated (0.52); PolyPhen benign (0.003); catalogued as COSV63252234; called by muse, mutect2, varscan2
- ITGAV | c.1389C>G p.I463M | Missense Mutation (SNP) | VAF 7/62 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.201); catalogued as COSV53713809; called by muse, mutect2, varscan2
- KCNG2 | c.1276G>A p.E426K | Missense Mutation (SNP) | VAF 14/28 reads (50%) | SIFT tolerated (0.69); PolyPhen benign (0.018); catalogued as rs754867366, COSV60268358; called by muse, mutect2, varscan2
- KCNH6 | c.1830C>G p.F610L | Missense Mutation (SNP) | VAF 10/20 reads (50%) | SIFT tolerated (0.06); PolyPhen benign (0.241); catalogued as COSV59004213; called by muse, mutect2, varscan2
- KDM1A | c.694G>A p.E232K | Missense Mutation (SNP) | VAF 15/88 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.715); catalogued as rs1239941955, COSV63086422, COSV63087608; called by muse, mutect2, varscan2
- KDM4D | c.895C>T p.R299* | Nonsense Mutation (SNP) | VAF 19/104 reads (18%) | catalogued as rs895780588, COSV58633807; called by muse, mutect2, varscan2
- KIF1C | c.494C>G p.S165C | Missense Mutation (SNP) | VAF 153/221 reads (69%) | SIFT deleterious (0); PolyPhen possibly damaging (0.557); catalogued as COSV57904930; called by muse, mutect2, varscan2
- KLRB1 | c.243C>A p.S81R | Missense Mutation (SNP) | VAF 48/190 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as COSV57589839; called by muse, mutect2, varscan2
- KMT2B | c.2018C>T p.A673V | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.039); catalogued as rs1193617786, COSV99386031; called by muse, mutect2
- LAMA3 | c.6696G>A p.M2232I (on ENST00000313654 / NM_198129.4; = p.M623I on NM_000227.6) | Missense Mutation (SNP) | VAF 46/149 reads (31%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as COSV52536107, COSV52536685; called by muse, mutect2, varscan2
- LAMA5 | c.3046G>A p.A1016T | Missense Mutation (SNP) | VAF 5/36 reads (14%) | SIFT tolerated (0.7); PolyPhen benign (0.011); catalogued as rs865915874, COSV53370656; called by muse, mutect2
- LHX8 | c.149C>T p.S50L | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as COSV53956303; called by mutect2, varscan2
- LIPE | c.679G>A p.E227K | Missense Mutation (SNP) | VAF 96/172 reads (56%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.187); catalogued as rs1163364110, COSV54922260, COSV54923319; called by muse, mutect2, varscan2
- MAP1A | c.2845G>C p.E949Q | Missense Mutation (SNP) | VAF 19/140 reads (14%) | SIFT tolerated (0.23); PolyPhen benign (0.001); catalogued as COSV55809685; called by muse, mutect2, varscan2
- MCF2L | c.645C>A p.D215E (on ENST00000375608; = p.D183E on NM_024979.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/88 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.047); catalogued as COSV65051090; called by muse, mutect2, varscan2
- MED27 | c.437G>A p.R146H | Missense Mutation (SNP) | VAF 27/107 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.747); catalogued as rs532293886, COSV52601808; called by muse, mutect2, varscan2
- METTL4 | c.1094T>G p.F365C | Missense Mutation (SNP) | VAF 25/115 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV60603839; called by muse, mutect2, varscan2
- MFSD5 | c.44C>A p.S15Y | Missense Mutation (SNP) | VAF 43/110 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.086); catalogued as COSV61565679; called by muse, mutect2, varscan2
- MLLT3 | c.735G>C p.E245D | Missense Mutation (SNP) | VAF 73/296 reads (25%) | SIFT tolerated (0.17); PolyPhen benign (0.007); catalogued as COSV63494432, COSV63498144; called by muse, mutect2, varscan2
- MMP10 | c.1001C>G p.S334C | Missense Mutation (SNP) | VAF 16/94 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV54246546; called by muse, mutect2, varscan2
- MORC1 | c.862G>A p.E288K | Missense Mutation (SNP) | VAF 19/135 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.336); catalogued as COSV51721853; called by muse, mutect2, varscan2
- MORC3 | c.2063C>T p.S688F | Missense Mutation (SNP) | VAF 52/90 reads (58%) | SIFT deleterious (0.01); PolyPhen benign (0.249); catalogued as COSV68688461; called by muse, mutect2, varscan2
- MSLNL | c.688C>T p.P230S | Missense Mutation (SNP) | VAF 9/13 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs544418530; called by muse, mutect2, varscan2
- MSMP | c.127C>G p.Q43E | Missense Mutation (SNP) | VAF 480/749 reads (64%) | SIFT deleterious (0.02); PolyPhen benign (0.373); catalogued as COSV65239690; called by muse, mutect2, varscan2
- MUC4 | c.143G>C p.G48A | Missense Mutation (SNP) | VAF 57/339 reads (17%) | SIFT tolerated, low confidence (1); PolyPhen possibly damaging (0.801); catalogued as COSV62126567, COSV62155830; called by muse, mutect2, varscan2
- MUC5B | c.8696C>G p.S2899C | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.858); catalogued as COSV101500181; called by mutect2, varscan2
- MXD4 | c.253G>A p.D85N | Missense Mutation (SNP) | VAF 10/55 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.776); catalogued as rs748103465, COSV61466385; called by muse, mutect2, varscan2
- MXRA5 | c.4810C>G p.Q1604E | Missense Mutation (SNP) | VAF 42/130 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.099); catalogued as COSV54238416; called by muse, mutect2, varscan2
- MYCN | c.370G>A p.E124K | Missense Mutation (SNP) | VAF 19/36 reads (53%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.967); catalogued as rs773995882, COSV55259059; called by muse, mutect2, varscan2
- MYO16 | c.3474C>G p.I1158M | Missense Mutation (SNP) | VAF 19/67 reads (28%) | SIFT tolerated (0.09); PolyPhen benign (0.033); catalogued as COSV62751609; called by muse, mutect2, varscan2
- MYOM2 | c.3130G>A p.D1044N | Missense Mutation (SNP) | VAF 40/86 reads (47%) | SIFT tolerated (1); PolyPhen benign (0.018); catalogued as COSV50720984; called by muse, mutect2, varscan2
- NADK | c.944G>A p.G315E | Missense Mutation (SNP) | VAF 28/64 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58273286; called by muse, mutect2, varscan2
- NBPF1 | c.733G>C p.E245Q | Missense Mutation (SNP) | VAF 187/1013 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as COSV101236256, COSV101236433, COSV67426530; called by muse, mutect2, varscan2
- NCKAP1L | c.451C>T p.R151W | Missense Mutation (SNP) | VAF 143/425 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs749529749, COSV53203011; called by muse, mutect2, varscan2
- NCL | c.496G>A p.D166N | Missense Mutation (SNP) | VAF 20/44 reads (45%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.096); catalogued as COSV59546383; called by muse, mutect2, varscan2
- NCOA5 | c.991G>A p.E331K | Missense Mutation (SNP) | VAF 8/71 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.006); catalogued as COSV51645020; called by muse, mutect2, varscan2
- NDUFS1 | c.757G>A p.V253I | Missense Mutation (SNP) | VAF 15/96 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.589); catalogued as rs746289681, COSV51910470; called by muse, mutect2, varscan2
- NEB | c.15952C>T p.R5318C | Missense Mutation (SNP) | VAF 10/57 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.888); catalogued as rs751870182, COSV51424210; called by muse, mutect2, varscan2
- NEIL3 | c.322G>C p.E108Q | Missense Mutation (SNP) | VAF 29/82 reads (35%) | SIFT tolerated (0.39); PolyPhen benign (0.107); catalogued as COSV52811164, COSV99219829; called by muse, mutect2, varscan2
- NIBAN1 | c.882G>C p.L294F | Missense Mutation (SNP) | VAF 15/274 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs768383065, COSV62285328; called by muse, mutect2
- NOL11 | c.1316G>T p.G439V | Missense Mutation (SNP) | VAF 91/280 reads (33%) | SIFT tolerated (0.15); PolyPhen benign (0.231); catalogued as COSV53523806; called by muse, mutect2, varscan2
- NPHP4 | c.3643T>C p.S1215P | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.135); catalogued as COSV65395465; called by muse, mutect2
- NPM3 | c.341T>G p.F114C | Missense Mutation (SNP) | VAF 3/13 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1564635550; called by muse, mutect2
- NSD2 | c.583C>G p.P195A | Missense Mutation (SNP) | VAF 9/80 reads (11%) | SIFT tolerated (0.11); PolyPhen benign (0.079); catalogued as COSV56391926; called by muse, mutect2, varscan2
- NSG1 | c.397G>A p.A133T | Missense Mutation (SNP) | VAF 20/137 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs758849842, COSV60373572; called by muse, mutect2, varscan2
- NT5E | c.1264G>A p.D422N | Missense Mutation (SNP) | VAF 23/85 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57628724; called by muse, mutect2, varscan2
- NTM | c.334C>A p.P112T | Missense Mutation (SNP) | VAF 14/112 reads (13%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.589); catalogued as COSV100869376, COSV66182356; called by muse, mutect2, varscan2
- NYNRIN | c.1489G>A p.D497N | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0); catalogued as COSV66843047; called by muse, mutect2, varscan2
- OFD1 | c.2395C>G p.R799G | Missense Mutation (SNP) | VAF 28/98 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.121); catalogued as COSV60796402; called by muse, mutect2, varscan2
- OIT3 | c.1526G>T p.C509F | Missense Mutation (SNP) | VAF 42/138 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61826373; called by muse, mutect2, varscan2
- OR2C3 | c.953C>T p.A318V | Missense Mutation (SNP) | VAF 17/63 reads (27%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.001); catalogued as rs147306837, COSV63574800; called by muse, mutect2, varscan2
- OR8D1 | c.64G>A p.E22K | Missense Mutation (SNP) | VAF 65/212 reads (31%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.489); catalogued as rs773986974, COSV63442462; called by muse, mutect2, varscan2
- OR8H3 | c.19G>A p.D7N | Missense Mutation (SNP) | VAF 50/248 reads (20%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as rs148197076, COSV57907799; called by muse, mutect2, varscan2
- OSBPL5 | c.2347G>C p.E783Q | Missense Mutation (SNP) | VAF 5/42 reads (12%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.756); catalogued as COSV55142435; called by muse, mutect2, varscan2
- PCARE | c.66G>C p.L22F | Missense Mutation (SNP) | VAF 16/129 reads (12%) | SIFT tolerated (0.94); PolyPhen benign (0.038); catalogued as COSV59055361; called by muse, mutect2
- PCDHA7 | c.1796C>T p.A599V | Missense Mutation (SNP) | VAF 22/105 reads (21%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.367); catalogued as COSV65344756; called by muse, mutect2, varscan2
- PDSS2 | c.208C>A p.R70S | Missense Mutation (SNP) | VAF 11/73 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100941753, COSV64648435; called by muse, mutect2, varscan2
- PDSS2 | c.56C>T p.S19F | Missense Mutation (SNP) | VAF 20/149 reads (13%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as rs1267747373, COSV64646324; called by muse, mutect2, varscan2
- PER2 | c.1705G>A p.E569K | Missense Mutation (SNP) | VAF 11/61 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.219); catalogued as rs369727558, COSV54528119; called by muse, mutect2, varscan2
- PERP | c.415C>G p.L139V | Missense Mutation (SNP) | VAF 28/141 reads (20%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.614); catalogued as COSV69827562; called by muse, mutect2, varscan2
- PFDN6 | c.292G>C p.E98Q | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.585); catalogued as rs373320781, COSV65842391; called by muse, mutect2, varscan2
- PFKFB3 | c.701G>T p.R234L | Missense Mutation (SNP) | VAF 18/143 reads (13%) | PolyPhen probably damaging (0.991); catalogued as COSV57989071; called by muse, mutect2, varscan2
- PIK3C3 | c.1168G>A p.E390K | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.514); catalogued as COSV100010193; called by muse, mutect2
- PLCB3 | c.3365C>G p.T1122R | Missense Mutation (SNP) | VAF 10/87 reads (11%) | SIFT tolerated (0.72); PolyPhen benign (0.24); catalogued as rs575846795, COSV54189114, COSV54189320, COSV54190771; called by muse, mutect2, varscan2
- PLEK | c.100G>C p.E34Q | Missense Mutation (SNP) | VAF 55/104 reads (53%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.927); catalogued as COSV52252083, COSV52252270; called by muse, mutect2, varscan2
- PLXNA2 | c.2828C>G p.T943R | Missense Mutation (SNP) | VAF 18/79 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.726); catalogued as COSV65441532; called by muse, mutect2, varscan2
- PPA1 | c.161C>G p.S54C | Missense Mutation (SNP) | VAF 13/31 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV64683951; called by muse, mutect2, varscan2
- PPP1R12A | c.1694C>G p.S565C | Missense Mutation (SNP) | VAF 58/362 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as COSV54109225; called by muse, mutect2, varscan2
- PPP1R3A | c.2560G>A p.E854K | Missense Mutation (SNP) | VAF 41/208 reads (20%) | SIFT tolerated (0.86); PolyPhen benign (0.024); catalogued as COSV52884496; called by muse, mutect2, varscan2
- PPP2R5B | c.979A>G p.T327A | Missense Mutation (SNP) | VAF 3/24 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.817); catalogued as COSV51210042; called by muse, mutect2
- PRAG1 | c.2194G>C p.D732H | Missense Mutation (SNP) | VAF 35/94 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100422507, COSV58162190; called by muse, mutect2, varscan2
- PRDM1 | c.803G>A p.R268H | Missense Mutation (SNP) | VAF 89/890 reads (10%) | SIFT tolerated (0.16); PolyPhen benign (0.005); catalogued as rs367766895; called by muse, mutect2, varscan2
- PRPF4B | c.2567G>C p.R856P | Missense Mutation (SNP) | VAF 34/165 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV61784421; called by muse, mutect2, varscan2
- PTGES2 | c.415G>C p.E139Q | Missense Mutation (SNP) | VAF 20/28 reads (71%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.999); catalogued as COSV52968617; called by muse, mutect2
- PTPRB | c.2878G>C p.E960Q | Missense Mutation (SNP) | VAF 21/83 reads (25%) | SIFT tolerated (0.1); PolyPhen benign (0.264); catalogued as COSV54243277; called by muse, mutect2, varscan2
- PTPRK | c.4276C>T p.R1426C (on ENST00000368215 / NM_001291984.2; = p.R1427C on NM_002844.4) | Missense Mutation (SNP) | VAF 20/92 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs1270609978, COSV100951424, COSV63899861; called by muse, mutect2, varscan2
- RABGAP1L | c.1278C>G p.F426L | Missense Mutation (SNP) | VAF 161/515 reads (31%) | SIFT tolerated (0.1); PolyPhen benign (0.411); catalogued as COSV52300918; called by muse, mutect2, varscan2
- RAP1A | c.259C>A p.Q87K | Missense Mutation (SNP) | VAF 26/127 reads (20%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.608); catalogued as COSV62728008; called by muse, mutect2, varscan2
- RECQL | c.1615C>G p.R539G | Missense Mutation (SNP) | VAF 29/175 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.469); catalogued as COSV53710110; called by muse, mutect2, varscan2
- RESF1 | c.109C>G p.Q37E | Missense Mutation (SNP) | VAF 24/149 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.223); catalogued as COSV57022896; called by muse, mutect2, varscan2
- RHCE | c.473G>A p.S158N | Missense Mutation (SNP) | VAF 37/239 reads (15%) | SIFT tolerated (0.44); PolyPhen benign (0.005); catalogued as rs758173067, COSV53801056; called by muse, mutect2, varscan2
- RIPK4 | c.1820G>A p.R607Q (on ENST00000352483; = p.R559Q on NM_020639.3) | Missense Mutation (SNP) | VAF 10/109 reads (9%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.839); catalogued as rs754589120, COSV60187847; called by muse, mutect2
- RNF121 | c.91G>C p.E31Q | Missense Mutation (SNP) | VAF 26/140 reads (19%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.756); catalogued as COSV62316883, COSV62317376; called by muse, mutect2, varscan2
- RNF123 | c.1982T>C p.V661A | Missense Mutation (SNP) | VAF 8/14 reads (57%) | SIFT tolerated (0.6); PolyPhen benign (0.007); catalogued as COSV59685720; called by mutect2, varscan2
- RNF165 | c.698C>T p.S233F | Missense Mutation (SNP) | VAF 20/118 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.194); catalogued as COSV53974309; called by muse, mutect2, varscan2
- RNLS | c.157C>A p.Q53K | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT tolerated (0.62); PolyPhen benign (0.003); catalogued as COSV59294630, COSV99045490; called by muse, mutect2, varscan2
- RPA3 | c.290G>C p.G97A | Missense Mutation (SNP) | VAF 31/262 reads (12%) | SIFT tolerated (0.42); PolyPhen benign (0.005); catalogued as COSV56188613; called by muse, mutect2, varscan2
- RPH3AL | c.577G>A p.E193K | Missense Mutation (SNP) | VAF 23/164 reads (14%) | SIFT tolerated (0.38); PolyPhen benign (0.175); catalogued as COSV58743457; called by muse, mutect2, varscan2
- RRBP1 | c.3727G>A p.E1243K (on ENST00000377813 / NM_001365613.2; = p.E810K on NM_004587.3) | Missense Mutation (SNP) | VAF 24/78 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as rs149077359, COSV55695929; called by muse, mutect2, varscan2
- RRM1 | c.217G>C p.D73H | Missense Mutation (SNP) | VAF 20/62 reads (32%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.796); catalogued as COSV56164600; called by muse, mutect2, varscan2
- RWDD1 | c.614G>C p.G205A | Missense Mutation (SNP) | VAF 10/61 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.962); catalogued as COSV63972584; called by muse, mutect2, varscan2
- RYR3 | c.3229G>A p.E1077K | Missense Mutation (SNP) | VAF 16/51 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.658); catalogued as COSV66793885; called by muse, mutect2, varscan2
- SALL1 | c.1795G>A p.E599K | Missense Mutation (SNP) | VAF 10/65 reads (15%) | SIFT tolerated (0.26); PolyPhen benign (0.045); catalogued as rs1422493863, COSV51758919; called by muse, mutect2, varscan2
- SBNO1 | c.289C>A p.P97T (on ENST00000420886; = p.P96T on NM_018183.5) | Missense Mutation (SNP) | VAF 15/92 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.981); catalogued as COSV57342473; called by muse, mutect2, varscan2
- SCG2 | c.502C>T p.P168S | Missense Mutation (SNP) | VAF 37/212 reads (17%) | SIFT tolerated (0.79); PolyPhen benign (0.009); catalogued as rs1163321876, COSV59540505; called by muse, mutect2, varscan2
- SCN5A | c.3577C>T p.R1193W (on ENST00000333535 / NM_198056.3; = p.R1192W on NM_000335.5) | Missense Mutation (SNP) | VAF 7/14 reads (50%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.802); catalogued as rs192379242; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SENP5 | c.1222G>A p.D408N | Missense Mutation (SNP) | VAF 29/140 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.397); catalogued as rs1255087373, COSV60208022; called by muse, mutect2, varscan2
- SLC22A12 | c.478G>A p.A160T | Missense Mutation (SNP) | VAF 23/133 reads (17%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.843); catalogued as rs1235171615, COSV60572527, COSV60573435; called by muse, mutect2, varscan2
- SLC24A3 | c.536G>C p.G179A | Missense Mutation (SNP) | VAF 46/225 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60121778; called by muse, mutect2, varscan2
- SLITRK1 | c.1697G>A p.R566K | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as COSV65674574; called by muse, mutect2, varscan2
- SMC4 | c.2043G>A p.M681I | Missense Mutation (SNP) | VAF 78/205 reads (38%) | SIFT tolerated (0.47); PolyPhen benign (0.157); catalogued as rs754076886, COSV61005644; called by muse, mutect2, varscan2
- SMG1 | c.10711G>C p.A3571P | Missense Mutation (SNP) | VAF 12/79 reads (15%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.503); catalogued as COSV67172010; called by muse, mutect2, varscan2
- SPTBN5 | c.10870C>T p.P3624S | Missense Mutation (SNP) | VAF 8/15 reads (53%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.477); catalogued as rs377294977; called by muse, mutect2, varscan2
- STAG3 | c.349G>C p.E117Q | Missense Mutation (SNP) | VAF 35/257 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.156); catalogued as COSV57931296; called by muse, mutect2, varscan2
- STIL | c.3809C>T p.S1270L | Missense Mutation (SNP) | VAF 87/163 reads (53%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs1232520547, COSV54550963; called by muse, mutect2, varscan2
- STK36 | c.1016C>A p.A339D | Missense Mutation (SNP) | VAF 20/128 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.075); catalogued as COSV55327352; called by muse, mutect2, varscan2
- STRADA | c.811G>A p.E271K (on ENST00000336174 / NM_001363786.1; = p.E234K on NM_153335.6) | Missense Mutation (SNP) | VAF 43/263 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55562268, COSV55563084; called by muse, mutect2, varscan2
- SUSD1 | c.550G>A p.E184K | Missense Mutation (SNP) | VAF 121/212 reads (57%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.858); catalogued as COSV62584113; called by muse, mutect2, varscan2
- SZT2 | c.2814+1G>A p.X938_splice | Splice Site (SNP) | VAF 16/213 reads (8%) | catalogued as COSV65170762; called by muse, mutect2
- TBC1D1 | c.212C>T p.S71F | Missense Mutation (SNP) | VAF 26/161 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.62); catalogued as rs1285525919, COSV54720668; called by muse, mutect2, varscan2
- TENM2 | c.1685T>A p.M562K (on ENST00000518659 / NM_001122679.2; = p.M330K on NM_001080428.3) | Missense Mutation (SNP) | VAF 51/213 reads (24%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as COSV69132596; called by muse, mutect2, varscan2
- TENM2 | c.3684C>G p.C1228W (on ENST00000518659 / NM_001122679.2; = p.C996W on NM_001080428.3) | Missense Mutation (SNP) | VAF 12/67 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV69132607; called by muse, mutect2, varscan2
- TIAM1 | c.2591C>T p.S864F | Missense Mutation (SNP) | VAF 50/405 reads (12%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.799); catalogued as COSV54555338; called by muse, mutect2, varscan2
- TIGD4 | c.1364A>G p.D455G | Missense Mutation (SNP) | VAF 20/78 reads (26%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as COSV58549843; called by muse, mutect2, varscan2
- TMPRSS11B | c.161C>T p.S54F | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT tolerated (0.36); PolyPhen benign (0.012); catalogued as COSV60292705; called by muse, mutect2, varscan2
- TOP1 | c.1312G>A p.E438K | Missense Mutation (SNP) | VAF 8/68 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV63694418; called by muse, mutect2, varscan2
- TP53 | c.1006G>T p.E336* | Nonsense Mutation (SNP) | VAF 28/41 reads (68%) | catalogued as CM044725, COSV52746809, COSV52814837, COSV53366474; called by muse, mutect2, varscan2
- TP53BP1 | c.40C>T p.Q14* | Nonsense Mutation (SNP) | VAF 45/212 reads (21%) | catalogued as rs1323524336; called by muse, mutect2, varscan2
- TRABD2A | c.932G>C p.R311P (on ENST00000409520 / NM_001277053.2; = p.R262P on NM_001080824.3) | Missense Mutation (SNP) | VAF 23/80 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); catalogued as COSV59103678, COSV59106170; called by muse, mutect2, varscan2
- TRIP12 | c.4142G>T p.S1381I | Missense Mutation (SNP) | VAF 46/293 reads (16%) | SIFT tolerated (0.05); PolyPhen benign (0.224); catalogued as COSV52258556; called by muse, mutect2, varscan2
- TRMT6 | c.1016A>G p.K339R | Missense Mutation (SNP) | VAF 87/144 reads (60%) | SIFT tolerated (0.4); PolyPhen benign (0.003); catalogued as COSV52544040; called by muse, mutect2, varscan2
- TRPT1 | c.706G>C p.E236Q (on ENST00000317459 / NM_001160393.1; = p.E187Q on NM_031472.4) | Missense Mutation (SNP) | VAF 15/143 reads (10%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.502); catalogued as COSV54174137, COSV54174980; called by muse, mutect2, varscan2
- TTC3 | c.369G>T p.K123N | Missense Mutation (SNP) | VAF 15/84 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.477); catalogued as COSV61291392, COSV61291643; called by muse, mutect2, varscan2
- TTC36 | c.171G>C p.Q57H | Missense Mutation (SNP) | VAF 15/101 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); catalogued as COSV57097020; called by muse, mutect2, varscan2
- TTC39B | c.1363G>C p.D455H | Missense Mutation (SNP) | VAF 30/138 reads (22%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.993); catalogued as COSV52611272; called by muse, mutect2, varscan2
- TTLL6 | c.1571C>A p.A524D (on ENST00000393382 / NM_001130918.3; = p.A217D on NM_173623.3) | Missense Mutation (SNP) | VAF 22/176 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.843); catalogued as COSV64977593; called by muse, varscan2
- TTN | c.6961C>G p.Q2321E (on ENST00000591111; = p.Q2275E on NM_003319.4) | Missense Mutation (SNP) | VAF 27/158 reads (17%) | PolyPhen benign (0.121); catalogued as COSV60058718, COSV60119128, COSV60286886; called by muse, mutect2, varscan2
- UBE2J1 | c.472G>C p.D158H | Missense Mutation (SNP) | VAF 23/82 reads (28%) | SIFT tolerated (0.13); PolyPhen benign (0.017); catalogued as COSV70561618; called by muse, mutect2, varscan2
- UBE3A | c.2475G>A p.M825I | Missense Mutation (SNP) | VAF 23/115 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.723); catalogued as COSV51665070; called by muse, mutect2, varscan2
- UCHL3 | c.45C>T p.V15= | Splice Region (SNP) | VAF 93/225 reads (41%) | catalogued as rs569027565, COSV66459771; called by muse, mutect2, varscan2
- UNC13C | c.2911T>A p.S971T | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT tolerated, low confidence (0.65); PolyPhen benign (0.017); catalogued as COSV52883288; called by muse, mutect2, varscan2
- USH2A | c.4562G>A p.R1521H | Missense Mutation (SNP) | VAF 16/69 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.07); catalogued as rs770394440, COSV56382512; called by muse, mutect2, varscan2
- USP48 | c.2151G>C p.K717N | Missense Mutation (SNP) | VAF 75/222 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV57610966; called by muse, mutect2, varscan2
- VAC14 | c.1186C>T p.H396Y | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.014); catalogued as rs953038005, COSV55751392, COSV55754444; called by muse, mutect2, varscan2
- VPS37C | c.217G>C p.E73Q | Missense Mutation (SNP) | VAF 47/175 reads (27%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.993); catalogued as COSV57108987, COSV57110236; called by muse, mutect2, varscan2
- WBP11 | c.257G>A p.R86H | Missense Mutation (SNP) | VAF 25/131 reads (19%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.917); catalogued as rs764884689, COSV53763236; called by muse, mutect2, varscan2
- WDR33 | c.664G>C p.D222H | Missense Mutation (SNP) | VAF 28/146 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59247573; called by muse, mutect2, varscan2
- WDR7 | c.4213G>A p.D1405N | Missense Mutation (SNP) | VAF 39/198 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV54354934; called by muse, mutect2, varscan2
- ZBED9 | c.3229G>A p.E1077K | Missense Mutation (SNP) | VAF 31/142 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.899); catalogued as rs868501361, COSV71729481; called by muse, mutect2, varscan2
- ZBTB47 | c.1484G>A p.C495Y | Missense Mutation (SNP) | VAF 37/91 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51764695; called by muse, mutect2, varscan2
- ZC3H13 | c.3037G>A p.D1013N | Missense Mutation (SNP) | VAF 11/77 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.922); catalogued as COSV54455823; called by muse, mutect2, varscan2
- ZNF146 | c.679C>G p.L227V | Missense Mutation (SNP) | VAF 23/184 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as rs1310700863, COSV61931335, COSV61931842, COSV61931929; called by muse, mutect2, varscan2
- ZNF189 | c.1759C>T p.Q587* | Nonsense Mutation (SNP) | VAF 26/83 reads (31%) | catalogued as COSV99407205, COSV99407277; called by muse, mutect2, varscan2
- ZNF26 | c.1027C>T p.Q343* | Nonsense Mutation (SNP) | VAF 19/80 reads (24%) | catalogued as COSV60806834; called by muse, mutect2, varscan2
- ZNF263 | c.20C>T p.S7F | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT tolerated (0.69); PolyPhen benign (0.003); catalogued as COSV54596772; called by muse, mutect2, varscan2
- ZNF33B | c.1584T>A p.Y528* | Nonsense Mutation (SNP) | VAF 47/160 reads (29%) | catalogued as COSV100847678; called by muse, mutect2, varscan2
- ZNF33B | c.1583A>T p.Y528F | Missense Mutation (SNP) | VAF 46/160 reads (29%) | SIFT tolerated (0.52); PolyPhen probably damaging (0.95); catalogued as COSV63942693; called by muse, mutect2, varscan2
- ZNF777 | c.612G>A p.M204I | Missense Mutation (SNP) | VAF 29/143 reads (20%) | SIFT tolerated (0.41); PolyPhen benign (0.076); catalogued as COSV56098204; called by muse, mutect2, varscan2
- ZNF831 | c.4030C>G p.L1344V | Missense Mutation (SNP) | VAF 26/84 reads (31%) | SIFT tolerated (0.31); PolyPhen benign (0.005); catalogued as COSV64041285; called by muse, mutect2, varscan2
- ZNFX1 | c.5654_5669del p.R1885Ifs*19 | Frame Shift Del (DEL) | VAF 20/176 reads (11%) | catalogued as COSV65598481; called by mutect2, pindel
- ZNFX1 | c.785C>G p.S262C | Missense Mutation (SNP) | VAF 27/134 reads (20%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.897); catalogued as COSV65576029; called by muse, mutect2, varscan2
- ZNHIT6 | c.661G>C p.E221Q | Missense Mutation (SNP) | VAF 72/197 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.971); catalogued as COSV65326648; called by muse, mutect2, varscan2
- ZSCAN10 | c.917G>A p.R306H (on ENST00000252463; = p.R361H on NM_032805.3) | Missense Mutation (SNP) | VAF 20/80 reads (25%) | SIFT tolerated (0.48); PolyPhen benign (0.013); catalogued as COSV52968503; called by muse, mutect2, varscan2
- AMER1 | c.1198G>T p.E400* | Nonsense Mutation (SNP) | VAF 19/63 reads (30%) | called by muse, mutect2, varscan2
- APOBR | c.1377G>C p.K459N (on ENST00000431282; = p.K468N on NM_018690.4) | Missense Mutation (SNP) | VAF 3/28 reads (11%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.534); called by muse, mutect2
- ATP1A4 | c.1904A>T p.K635M | Missense Mutation (SNP) | VAF 28/318 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.88); called by muse, mutect2
- CCDC180 | c.858G>A p.M286I | Missense Mutation (SNP) | VAF 32/164 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.167); called by muse, mutect2
- CHEK2 | c.1500_1504+18del p.X500_splice (on ENST00000382580 / NM_001005735.2; = p.X457_splice on NM_007194.4) | Splice Site (DEL) | VAF 8/53 reads (15%) | called by mutect2, pindel
- DBNDD1 | c.259G>C p.E87Q (on ENST00000002501 / NM_001042610.3; = p.E107Q on NM_024043.3) | Missense Mutation (SNP) | VAF 3/17 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- DIAPH2 | c.3269C>G p.S1090* | Nonsense Mutation (SNP) | VAF 8/11 reads (73%) | called by muse, mutect2, varscan2
- DNAH11 | c.730G>T p.E244* | Nonsense Mutation (SNP) | VAF 27/65 reads (42%) | called by muse, mutect2, varscan2
- DYNC2I1 | c.2365C>G p.Q789E | Missense Mutation (SNP) | VAF 3/23 reads (13%) | SIFT tolerated (0.1); PolyPhen benign (0.11); called by muse, mutect2
- FAM120B | c.2334_2335dup p.G779Afs*8 | Frame Shift Ins (INS) | VAF 16/69 reads (23%) | called by mutect2, pindel, varscan2
- GPR179 | c.4765G>A p.A1589T (on ENST00000621958; = p.A1588T on NM_001004334.4) | Missense Mutation (SNP) | VAF 132/427 reads (31%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.637); called by muse, mutect2, varscan2
- HORMAD1 | c.946C>T p.Q316* | Nonsense Mutation (SNP) | VAF 6/94 reads (6%) | called by muse, mutect2
- LSM14B | c.428G>A p.G143E | Missense Mutation (SNP) | VAF 5/11 reads (45%) | SIFT deleterious (0.02); PolyPhen benign (0.36); called by muse, mutect2, varscan2
- M1AP | c.520C>T p.Q174* | Nonsense Mutation (SNP) | VAF 25/169 reads (15%) | called by muse, mutect2, varscan2
- MAGEE1 | c.925C>T p.Q309* | Nonsense Mutation (SNP) | VAF 4/28 reads (14%) | called by muse, mutect2
- MAN1C1 | c.712G>T p.E238* | Nonsense Mutation (SNP) | VAF 26/67 reads (39%) | called by muse, mutect2, varscan2
- MAPK8IP1 | c.1027G>C p.E343Q | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT tolerated (0.1); PolyPhen benign (0.143); called by muse, mutect2
- NCOA2 | c.3011C>G p.S1004C | Missense Mutation (SNP) | VAF 6/71 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.246); called by muse, mutect2
- NEDD9 | c.2296C>T p.Q766* | Nonsense Mutation (SNP) | VAF 36/403 reads (9%) | called by muse, mutect2
- NOL10 | c.708G>C p.L236F | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2
- NT5C1A | c.136C>T p.P46S | Missense Mutation (SNP) | VAF 5/106 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.902); called by muse, mutect2
- PIK3C2B | c.2896_2899del p.Q966Sfs*20 | Frame Shift Del (DEL) | VAF 34/263 reads (13%) | called by mutect2, pindel, varscan2
- PXDNL | c.1592C>T p.S531L | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT tolerated (0.11); PolyPhen benign (0.103); called by muse, mutect2
- REV3L | c.9184C>T p.Q3062* | Nonsense Mutation (SNP) | VAF 32/139 reads (23%) | called by muse, mutect2, varscan2
- SFMBT1 | c.2600G>C p.*867Sext*6 | Nonstop Mutation (SNP) | VAF 65/110 reads (59%) | called by muse, mutect2, varscan2
- SPAG11B | c.311A>G p.*104Wext*20 | Nonstop Mutation (SNP) | VAF 25/100 reads (25%) | called by muse, mutect2, varscan2
- THOC5 | c.165C>G p.Y55* | Nonsense Mutation (SNP) | VAF 29/148 reads (20%) | called by muse, mutect2, varscan2
- TTN | c.48510G>A p.W16170* (on ENST00000591111; = p.W8746* on NM_003319.4) | Nonsense Mutation (SNP) | VAF 33/228 reads (14%) | called by muse, mutect2, varscan2
- ZBTB8A | c.49C>T p.Q17* | Nonsense Mutation (SNP) | VAF 26/66 reads (39%) | called by muse, mutect2, varscan2
- ZNF146 | c.86C>G p.S29* | Nonsense Mutation (SNP) | VAF 24/102 reads (24%) | called by muse, varscan2
- ZNF514 | c.667C>T p.Q223* | Nonsense Mutation (SNP) | VAF 50/244 reads (20%) | called by muse, mutect2, varscan2
- ABCA13 | c.9349C>T p.L3117= | Silent (SNP) | VAF 22/132 reads (17%) | catalogued as COSV71289460; called by muse, mutect2, varscan2
- ACP2 | c.378G>A p.G126= | Silent (SNP) | VAF 18/158 reads (11%) | catalogued as COSV57042832; called by muse, mutect2, varscan2
- AL121899.2 | c.1863G>A p.L621= | Silent (SNP) | VAF 7/25 reads (28%) | catalogued as rs753749322, COSV67350995; called by muse, mutect2, varscan2
- ANO9 | c.282C>T p.L94= | Silent (SNP) | VAF 20/106 reads (19%) | catalogued as COSV60449767; called by muse, mutect2, varscan2
- ATG101 | c.312G>A p.Q104= | Silent (SNP) | VAF 29/88 reads (33%) | catalogued as COSV61085298; called by muse, mutect2, varscan2
- BBOF1 | c.1491C>T p.I497= | Silent (SNP) | VAF 28/115 reads (24%) | catalogued as COSV63246569; called by muse, mutect2, varscan2
- BNC2 | c.1107C>T p.S369= | Silent (SNP) | VAF 16/162 reads (10%) | catalogued as rs758963232, COSV66149080; called by muse, mutect2
- CACNG4 | c.84C>T p.I28= | Silent (SNP) | VAF 10/33 reads (30%) | catalogued as COSV50925575, COSV50928359; called by muse, mutect2, varscan2
- CAD | c.1269G>A p.L423= | Silent (SNP) | VAF 45/273 reads (16%) | catalogued as COSV53027818, COSV53028297; called by muse, mutect2, varscan2
- CAVIN4 | c.594C>T p.I198= | Silent (SNP) | VAF 74/115 reads (64%) | catalogued as COSV56867427; called by muse, mutect2, varscan2
- CDHR3 | c.2472C>T p.V824= | Silent (SNP) | VAF 18/43 reads (42%) | catalogued as COSV58418137; called by muse, mutect2, varscan2
- CHFR | c.1836G>T p.L612= (on ENST00000432561 / NM_001161345.1; = p.L571= on NM_018223.2) | Silent (SNP) | VAF 32/67 reads (48%) | catalogued as COSV57175262; called by muse, mutect2, varscan2
- CMTM5 | c.24G>A p.R8= | Silent (SNP) | VAF 11/66 reads (17%) | catalogued as COSV59306211; called by muse, mutect2, varscan2
- DCK | c.306C>T p.L102= | Silent (SNP) | VAF 25/134 reads (19%) | catalogued as COSV54377489, COSV54378770; called by muse, mutect2, varscan2
- DDX39B | c.765G>A p.T255= | Silent (SNP) | VAF 20/75 reads (27%) | catalogued as COSV63331499, COSV63331846; called by muse, mutect2, varscan2
- DMBT1 | c.993C>T p.V331= | Silent (SNP) | VAF 15/80 reads (19%) | catalogued as rs748627428, COSV57546849; called by muse, mutect2, varscan2
- DOCK2 | c.864C>G p.L288= | Silent (SNP) | VAF 20/109 reads (18%) | catalogued as COSV56963372; called by muse, mutect2, varscan2
- EPHB2 | c.450G>A p.V150= | Silent (SNP) | VAF 7/64 reads (11%) | catalogued as COSV65863131; called by muse, mutect2, varscan2
- FKBP2 | c.255C>T p.V85= | Silent (SNP) | VAF 17/75 reads (23%) | catalogued as rs1485719811, COSV58588086; called by muse, mutect2, varscan2
- FSIP2 | c.19707G>C p.L6569= | Silent (SNP) | VAF 19/94 reads (20%) | catalogued as rs1215249913, COSV100554872, COSV58078792; called by muse, mutect2, varscan2
- HTT | c.8769C>T p.L2923= | Silent (SNP) | VAF 7/30 reads (23%) | catalogued as COSV61863556; called by muse, mutect2, varscan2
- HUNK | c.412C>T p.L138= | Silent (SNP) | VAF 46/209 reads (22%) | catalogued as COSV54229517; called by muse, mutect2, varscan2
- HYLS1 | c.405G>A p.L135= | Silent (SNP) | VAF 52/176 reads (30%) | catalogued as COSV54990980; called by muse, mutect2, varscan2
- IL18RAP | c.915G>A p.A305= | Silent (SNP) | VAF 11/67 reads (16%) | catalogued as rs779394612, COSV51826574; called by muse, mutect2, varscan2
- ITPRID1 | c.339C>T p.I113= | Silent (SNP) | VAF 14/113 reads (12%) | catalogued as COSV60074284; called by muse, mutect2
- KCNH8 | c.1242C>T p.G414= | Silent (SNP) | VAF 62/609 reads (10%) | catalogued as COSV60466332; called by muse, mutect2, varscan2
- KIF18A | c.2205C>T p.I735= | Silent (SNP) | VAF 59/220 reads (27%) | catalogued as COSV54183976; called by muse, mutect2, varscan2
- KRT79 | c.1203C>G p.L401= | Silent (SNP) | VAF 25/74 reads (34%) | catalogued as COSV57940459; called by muse, mutect2, varscan2
- LSM14A | c.150G>A p.P50= | Silent (SNP) | VAF 39/256 reads (15%) | catalogued as rs749529069, COSV70885209; called by muse, mutect2, varscan2
- MAP4 | c.1914G>C p.P638= | Silent (SNP) | VAF 77/216 reads (36%) | catalogued as COSV53135932, COSV53138517; called by muse, mutect2, varscan2
- MED12L | c.5685C>T p.L1895= | Silent (SNP) | VAF 52/118 reads (44%) | catalogued as COSV56382094; called by muse, mutect2, varscan2
- MEX3A | c.507G>A p.P169= | Silent (SNP) | VAF 11/28 reads (39%) | catalogued as COSV64142637; called by muse, mutect2, varscan2
- MFNG | c.822C>T p.L274= | Silent (SNP) | VAF 30/152 reads (20%) | catalogued as COSV63690406; called by muse, varscan2
- MMAB | c.318G>A p.K106= | Silent (SNP) | VAF 41/168 reads (24%) | catalogued as COSV57170433; called by muse, mutect2, varscan2
- MYH9 | c.3054C>T p.L1018= | Silent (SNP) | VAF 23/87 reads (26%) | catalogued as rs766890055, COSV53387621; called by muse, mutect2, varscan2
- N4BP2 | c.3561C>T p.N1187= | Silent (SNP) | VAF 67/176 reads (38%) | catalogued as rs368709827; called by muse, mutect2, varscan2
- NLRP4 | c.2364C>T p.F788= | Silent (SNP) | VAF 66/121 reads (55%) | catalogued as rs758966225, COSV56715619, COSV56722096; called by muse, mutect2, varscan2
- NPAS2 | c.1029C>T p.F343= | Silent (SNP) | VAF 22/113 reads (19%) | catalogued as rs1201983169, COSV59558524; called by muse, mutect2, varscan2
- NPR3 | c.522C>G p.L174= | Silent (SNP) | VAF 12/150 reads (8%) | catalogued as COSV54088690; called by muse, mutect2
- OBSCN | c.6666C>T p.L2222= | Silent (SNP) | VAF 7/15 reads (47%) | catalogued as rs1291218409, COSV52783320; called by muse, mutect2, varscan2
- ORC3 | c.744C>G p.L248= | Silent (SNP) | VAF 22/84 reads (26%) | catalogued as COSV57640955; called by muse, mutect2, varscan2
- OVCH1 | c.2868C>G p.V956= | Silent (SNP) | VAF 43/149 reads (29%) | catalogued as COSV58964245; called by muse, mutect2, varscan2
- OXCT1 | c.684G>A p.R228= | Silent (SNP) | VAF 39/237 reads (16%) | catalogued as COSV52171997; called by muse, mutect2, varscan2
- PCNX1 | c.108C>G p.L36= | Silent (SNP) | VAF 8/22 reads (36%) | catalogued as COSV53096010; called by muse, mutect2, varscan2
- PIPOX | c.36G>A p.V12= | Silent (SNP) | VAF 16/91 reads (18%) | catalogued as COSV60142275; called by muse, mutect2, varscan2
- PNKD | c.1134G>A p.L378= | Silent (SNP) | VAF 15/61 reads (25%) | catalogued as COSV51232774; called by muse, mutect2, varscan2
- PPFIA1 | c.2439G>A p.K813= | Silent (SNP) | VAF 30/97 reads (31%) | catalogued as rs1456630727, COSV54136172; called by muse, mutect2, varscan2
- PPFIA2 | c.1944G>C p.T648= | Silent (SNP) | VAF 37/160 reads (23%) | catalogued as COSV61036085; called by muse, mutect2, varscan2
- PRKDC | c.3744C>T p.F1248= | Silent (SNP) | VAF 5/32 reads (16%) | catalogued as rs200729621, COSV58054804; ClinVar: conflicting interpretations of pathogenicity; called by muse, mutect2, varscan2
- PRR11 | c.399G>A p.L133= | Silent (SNP) | VAF 14/82 reads (17%) | catalogued as COSV51877103; called by muse, mutect2, varscan2
- PRRC2C | c.2424G>A p.L808= (on ENST00000367742; = p.L806= on NM_015172.4) | Silent (SNP) | VAF 5/41 reads (12%) | catalogued as COSV58910770; called by muse, mutect2
- PTGES2 | c.306G>A p.L102= | Silent (SNP) | VAF 40/67 reads (60%) | catalogued as COSV52968627, COSV99476383; called by muse, mutect2, varscan2
- PTPRN2 | c.1263C>G p.L421= | Silent (SNP) | VAF 31/118 reads (26%) | catalogued as rs555402048, COSV67042550; called by muse, mutect2, varscan2
- RCAN3 | c.213C>G p.L71= | Silent (SNP) | VAF 16/218 reads (7%) | catalogued as COSV65558204, COSV65558600; called by muse, mutect2
- SALL1 | c.2163G>A p.L721= | Silent (SNP) | VAF 13/78 reads (17%) | catalogued as COSV51757350; called by muse, mutect2, varscan2
- SCN5A | c.3996G>A p.P1332= (on ENST00000333535 / NM_198056.3; = p.P1331= on NM_000335.5) | Silent (SNP) | VAF 20/71 reads (28%) | catalogued as rs775789293, COSV61127303; ClinVar: uncertain significance / benign; called by muse, mutect2, varscan2
- SEMA6B | c.1281G>C p.L427= | Silent (SNP) | VAF 20/43 reads (47%) | catalogued as COSV56704215; called by muse, mutect2, varscan2
- SLC26A4 | c.636G>A p.V212= | Silent (SNP) | VAF 65/272 reads (24%) | catalogued as COSV55917267; called by muse, mutect2, varscan2
- SP2 | c.360C>T p.I120= | Silent (SNP) | VAF 33/141 reads (23%) | catalogued as COSV65064338; called by muse, mutect2, varscan2
- SPATA31D1 | c.1701G>A p.L567= | Silent (SNP) | VAF 28/165 reads (17%) | catalogued as rs1564174286, COSV61196797; called by muse, mutect2, varscan2
- SPIN1 | c.678G>A p.S226= | Silent (SNP) | VAF 23/141 reads (16%) | catalogued as rs780946391, COSV65499129; called by muse, mutect2, varscan2
- SPRING1 | c.57C>T p.L19= | Silent (SNP) | VAF 8/45 reads (18%) | catalogued as rs910550417, COSV54339021; called by muse, mutect2, varscan2
- TAS2R14 | c.953G>A p.*318= | Silent (SNP) | VAF 14/93 reads (15%) | catalogued as COSV101114694; called by muse, mutect2, varscan2
- TBX5 | c.1188C>T p.I396= | Silent (SNP) | VAF 18/105 reads (17%) | catalogued as COSV59862086; called by muse, mutect2, varscan2
- TENM3 | c.1992C>T p.S664= | Silent (SNP) | VAF 19/77 reads (25%) | catalogued as COSV69310520; called by muse, mutect2, varscan2
- TET2 | c.105G>A p.Q35= | Silent (SNP) | VAF 15/60 reads (25%) | catalogued as COSV54415336; called by muse, mutect2, varscan2
- TMEM214 | c.561G>A p.A187= | Silent (SNP) | VAF 51/158 reads (32%) | catalogued as rs777196529, COSV53192956; called by muse, mutect2, varscan2
- TMEM245 | c.1971C>G p.L657= | Silent (SNP) | VAF 16/99 reads (16%) | catalogued as COSV65823130; called by muse, mutect2, varscan2
- TNRC18 | c.7281C>G p.L2427= | Silent (SNP) | VAF 14/30 reads (47%) | called by muse, mutect2, varscan2
- TRIM55 | c.436C>T p.L146= | Silent (SNP) | VAF 18/150 reads (12%) | catalogued as COSV52544770, COSV52546938; called by muse, mutect2, varscan2
- WASF3 | c.123G>A p.L41= | Silent (SNP) | VAF 78/238 reads (33%) | catalogued as COSV58967162; called by muse, mutect2, varscan2
- WDFY3 | c.1128C>T p.H376= | Silent (SNP) | VAF 25/137 reads (18%) | catalogued as COSV55703515; called by muse, mutect2, varscan2
- WDR38 | c.261C>T p.V87= | Silent (SNP) | VAF 21/106 reads (20%) | catalogued as rs773223375, COSV62161120; called by muse, mutect2, varscan2
- YARS1 | c.459A>T p.V153= | Silent (SNP) | VAF 32/190 reads (17%) | catalogued as COSV65114086; called by muse, mutect2, varscan2
- ZFHX4 | c.7440G>A p.T2480= | Silent (SNP) | VAF 116/138 reads (84%) | catalogued as COSV50494976; called by muse, mutect2, varscan2
- ZMIZ1 | c.549G>A p.G183= | Silent (SNP) | VAF 15/58 reads (26%) | catalogued as COSV57897245; called by muse, mutect2, varscan2
- ZNF831 | c.4923C>T p.A1641= | Silent (SNP) | VAF 50/142 reads (35%) | catalogued as rs769053542, COSV64041291; called by muse, mutect2, varscan2
- CDC37P1 | n.860C>T | RNA (SNP) | VAF 5/26 reads (19%) | catalogued as rs1353222852; called by muse, mutect2, varscan2
- DDX39B | c.616+69G>C | Intron (SNP) | VAF 22/120 reads (18%) | catalogued as COSV100795205; called by muse, mutect2, varscan2
- DLG2 | c.205-65660G>A | Intron (SNP) | VAF 61/141 reads (43%) | catalogued as COSV54652449; called by muse, mutect2, varscan2
- HSD17B4 | c.-158C>G | 5'UTR (SNP) | VAF 19/69 reads (28%) | catalogued as COSV56336363; called by muse, mutect2, varscan2
- MIRLET7A2 | n.6G>A | RNA (SNP) | VAF 49/116 reads (42%) | called by muse, mutect2, varscan2
- NBR2 | n.333C>T | RNA (SNP) | VAF 9/52 reads (17%) | called by muse, mutect2, varscan2
- RBM44 | c.-98-2689C>T | Intron (SNP) | VAF 9/37 reads (24%) | catalogued as COSV57630232; called by muse, mutect2, varscan2
- ZMYND19 | c.*2G>A | 3'UTR (SNP) | VAF 15/73 reads (21%) | catalogued as rs751144309, COSV99483505; called by muse, mutect2, varscan2
- ZNF493 | c.-132+7983T>G | Intron (SNP) | VAF 35/272 reads (13%) | catalogued as COSV60550438; called by muse, mutect2, varscan2
